Gene-level copy-number profile of tumor specimen TCGA-XF-AAMX-01A from TCGA case TCGA-XF-AAMX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 87.3 years (31,884 days).
Specimen TCGA-XF-AAMX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.074c98bd-ae0c-4f93-a18a-024faecfe555.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a3d504ee-67ca-493a-99ea-934d19f41b43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 9,343; copy number 2: 19,681; copy number 3: 16,383; copy number 4: 10,157; copy number 5: 2,945; copy number 6: 522; copy number 7: 310; copy number 8: 188; copy number 9: 167; copy number 10: 2; copy number 11: 24; copy number 12: 13; copy number 14: 24; copy number 15: 9; copy number 23: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMX-01A-11D-A42D-01): tumor purity 0.86, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:30,606,601–30,694,142, 1 gene (within-gene range 0–3): TGFBR2.
- chr5:107,376,889–107,670,937, 1 gene (within-gene range 0–1): EFNA5.
- chr10:87,500,337–88,259,372, 18 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr14:28,592,223–28,830,204, 9 genes: LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281.
- chr14:28,857,384–28,858,701, 1 gene: AL122126.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,191 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,363,091–150,913,292, 27 genes, copy number 6 (within-gene range 4–6): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51.
- chr1:159,712,289–162,386,812, 131 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr1:165,581,613–168,376,876, 74 genes, copy number 5–11 (broad region; genes not listed).
- chr2:38,814–3,644,644, 65 genes, copy number 5 (broad region; genes not listed).
- chr2:20,447,074–22,536,322, 31 genes, copy number 5 (within-gene range 4–5): RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850, AC115619.1, APOB, AC010872.1, AC010872.2, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830.
- chr2:34,692,290–40,255,209, 90 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:44,065,894–48,314,224, 86 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:60,057,601–62,262,671, 58 genes, copy number 5: AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P.
- chr3:33,496,245–37,183,689, 40 genes, copy number 5 (within-gene range 3–5): CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1, RFC3P1, STAC, NBPF21P, RN7SKP227, DCLK3, HSPD1P6, LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1.
- chr3:106,449,775–108,529,322, 34 genes, copy number 5 (within-gene range 3–5): LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15.
- chr6:5,261,044–6,995,727, 29 genes, copy number 5: FARS2, AL121978.1, AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1.
- chr7:70,972–31,708,455, 561 genes, copy number 5–6 (broad region; genes not listed).
- chr9:34,610,486–43,045,120, 281 genes, copy number 5 (broad region; genes not listed).
- chr9:83,596,444–93,036,236, 183 genes, copy number 5 (broad region; genes not listed).
- chr11:76,349,956–77,994,671, 43 genes, copy number 5: THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4.
- chr11:78,139,771–87,721,233, 131 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:118,572,390–129,279,324, 301 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:2,603,350–4,026,658, 46 genes, copy number 5: CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1.
- chr12:18,242,961–23,188,807, 71 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:23,529,504–27,502,185, 70 genes, copy number 6 (broad region; genes not listed).
- chr12:47,187,812–47,485,722, 12 genes, copy number 6: MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1.
- chr12:48,327,942–48,628,836, 20 genes, copy number 9: AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA, OR11M1P.
- chr12:119,334,712–122,626,396, 122 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:125,808,668–133,214,832, 223 genes, copy number 5 (broad region; genes not listed).
- chr14:26,443,090–27,295,516, 9 genes, copy number 9 (within-gene range 3–9): NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:34,675,891–36,656,163, 56 genes, copy number 5 (within-gene range 4–5): RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2.
- chr15:38,628,005–41,773,081, 111 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:9,068,554–10,182,928, 18 genes, copy number 5 (within-gene range 4–5): AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11.
- chr17:30,978,610–32,381,885, 60 genes, copy number 5 (within-gene range 4–5): AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3, AC007923.2, RNU6-1134P, GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207.
- chr17:58,519,837–67,033,398, 264 genes, copy number 5–23 (within-gene range 3–23) (broad region; genes not listed).
- chr17:68,206,076–69,327,244, 25 genes, copy number 5–10 (within-gene range 4–10): AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4.
- chr17:80,036,632–82,490,537, 149 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:27,932,879–29,650,440, 11 genes, copy number 5–6: CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr20:33,912,323–35,147,336, 43 genes, copy number 5: TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1.
- chr20:42,072,752–43,727,002, 26 genes, copy number 5 (within-gene range 4–5): PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L.
- chr20:51,782,331–64,313,132, 306 genes, copy number 5 (broad region; genes not listed).
- chr21:10,328,411–15,880,069, 83 genes, copy number 5–14 (broad region; genes not listed).
- chr21:17,210,469–17,894,485, 19 genes, copy number 5: NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3.
- chr22:20,602,595–22,520,270, 151 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr22:32,039,490–36,179,385, 90 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,473. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
